CCDI case PBCFLV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/924b7404-527c-400d-8aa3-a319e5a7741d

Demographics
Sex at birth: female.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (649 days).

Biospecimens (3 samples)
- Sample 0DR1XF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR1YQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR20M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
